Gene-level copy-number profile of tumor specimen ALCH-B2U9-TTP1-A from ALCHEMIST case ALCH-B2U9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.8 years (20,739 days).
Specimen ALCH-B2U9-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 38d255f6-1b7c-48b0-a957-d116fd2ae848.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2U9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/30f40018-85f6-44d4-82ce-b0b6011488c2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 94; copy number 1: 22,676; copy number 2: 28,896; copy number 3: 6,665; copy number 4: 24; copy number 5: 13; copy number 9: 13; copy number 38: 2; copy number 42: 1.

Homozygous deletions (total copy number 0; autosomes only): 94 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,118,534–87,120,980, 1 gene: ANAPC1P3.
- chr3:138,434,586–138,481,686, 1 gene: ESYT3.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr8:43,539,137–43,674,591, 5 genes: AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr9:64,637,845–64,652,556, 1 gene: AL445665.1.
- chr9:68,302,867–68,330,626, 3 genes (within-gene range 0–1): FOXD4L3, AL353608.3, AL353608.1.
- chr9:68,393,881–68,406,500, 1 gene (within-gene range 0–1): AL161457.2.
- chr10:1,526,637–1,556,984, 1 gene (within-gene range 0–1): ADARB2-AS1.
- chr10:14,986,942–15,021,863, 4 genes (within-gene range 0–1): OR7E110P, OR7E26P, OR7E115P, DCLRE1CP1.
- chr10:86,264,694–86,264,788, 1 gene (within-gene range 0–1): MIR346.
- chr10:122,697,709–122,699,846, 1 gene: C10orf120.
- chr10:129,693,722–129,702,117, 1 gene (within-gene range 0–1): AL157832.2.
- chr10:131,092,391–131,311,721, 2 genes: TCERG1L, TCERG1L-AS1.
- chr11:76,782,251–76,804,555, 3 genes (within-gene range 0–2): TSKU, AP003119.2, AP003119.3.
- chr12:31,012,503–31,104,799, 4 genes: AC008013.2, DDX11-AS1, DDX11, SNORA75.
- chr12:114,104,542–114,105,931, 1 gene (within-gene range 0–1): GLULP5.
- chr13:112,052,078–112,331,225, 8 genes: AL138691.1, SOX1-OT, SOX1, AL356961.1, LINC00404, LINC01070, LINC01043, LINC01044.
- chr15:25,169,337–25,247,426, 43 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42.
- chr15:34,489,002–34,521,791, 3 genes: HNRNPLP2, FSCN1P1, DNM1P5.
- chr15:77,568,970–77,608,888, 1 gene: AC046168.2.
- chr15:77,660,052–77,668,074, 1 gene (within-gene range 0–1): LINGO1-AS2.
- chr16:84,039,918–84,040,033, 1 gene (within-gene range 0–2): RNA5SP432.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–1): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 29 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,379,880–87,380,767, 1 gene, copy number 5: AC068279.1.
- chr12:57,674,665–57,984,761, 24 genes, copy number 5–9: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr21:43,414,483–43,479,534, 4 genes, copy number 5–42: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 22,675. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
